Somatic mutation profile of tumor specimen C3N-02298-02 (aliquot CPT0181540011) from CPTAC case C3N-02298, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 83.1 years (30,352 days).
Specimen C3N-02298-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25309198-837f-4ed2-927f-29ce0659823d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02298-31 (Blood Derived Normal), aliquot CPT0181590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9953b80a-70c4-4474-90de-020bba3891d3

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Frame Shift Ins 4, Frame Shift Del 3, Intron 2, Splice Site 2, 5'UTR 1, RNA 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 221/628 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 168/240 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APBA2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 105/355 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs1416887852, COSV68792476; called by muse, mutect2, varscan2
- ARMH1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1163039804; called by muse, mutect2, varscan2
- BUD23 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as rs782377734; called by muse, mutect2, varscan2
- CCDC85A | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs764849312, COSV68154259; called by muse, mutect2, varscan2
- CDH20 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs763645248, COSV53011757; called by muse, mutect2, varscan2
- CFH | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 115/523 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs374159003; called by muse, mutect2, varscan2
- COL12A1 | c.4633G>A p.V1545I | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV59409902; called by muse, mutect2, varscan2
- EFHC1 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs777529248; called by muse, mutect2
- ESR1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 132/451 reads (29%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.904); catalogued as COSV52793245, COSV52795871, COSV99241853; called by muse, mutect2, varscan2
- FAM234A | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.173); catalogued as rs751322019; called by muse, mutect2, varscan2
- FAM47A | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.923); catalogued as rs1241853720, COSV60499162; called by muse, varscan2
- FAM47A | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.791); catalogued as COSV60499319; called by muse, varscan2
- ILKAP | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs139306246, COSV54518744; called by muse, mutect2, varscan2
- KATNAL2 | c.1261G>A p.D421N (on ENST00000356157 / NM_001353899.1; = p.D349N on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.93); catalogued as rs566388347; called by muse, mutect2, varscan2
- MAN2B2 | c.2933G>A p.G978D | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs960229063; called by muse, mutect2, varscan2
- NELL1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.982); catalogued as rs772357355; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 68/254 reads (27%) | catalogued as rs146650273; called by pindel, varscan2
- RASL10A | c.588_601del p.H196Qfs*60 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as rs1269872451; called by mutect2, varscan2
- RYR2 | c.9778C>T p.R3260W | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs765325906, COSV63658681; called by muse, mutect2, varscan2
- SAGE1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs781926163, COSV61017933; called by muse, mutect2, varscan2
- SPG11 | c.2801A>G p.Y934C | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs777473151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIAM2 | c.1744C>A p.P582T | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59696783; called by muse, mutect2, varscan2
- WTAP | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61610446, COSV61610540; called by muse, mutect2, varscan2
- ZNF222 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 148/417 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200245363, COSV51827910; called by muse, mutect2, varscan2
- CHRNA2 | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 199/640 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- GATA5 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GOLGA6L2 | c.243+1G>A p.X81_splice | Splice Site (SNP) | VAF 116/342 reads (34%) | called by muse, mutect2, varscan2
- HDAC2 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HSD17B10 | c.192C>T p.D64= | Splice Region (SNP) | VAF 172/470 reads (37%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, varscan2
- IGSF1 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ISYNA1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- KCNT2 | c.622T>C p.C208R | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- KRTCAP3 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 199/904 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- MROH9 | c.2225del p.L742Yfs*18 | Frame Shift Del (DEL) | VAF 60/325 reads (18%) | called by mutect2, pindel, varscan2
- NUGGC | c.1298C>A p.T433N | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T1 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PCDHA10 | c.394T>G p.F132V | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PIK3R1 | c.1816dup p.Q606Pfs*8 (on ENST00000521381 / NM_181523.3; = p.Q336Pfs*8 on NM_181504.4) | Frame Shift Ins (INS) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- PTEN | c.156dup p.V53Cfs*10 | Frame Shift Ins (INS) | VAF 46/226 reads (20%) | called by mutect2, pindel, varscan2
- SLC24A1 | c.2471A>C p.N824T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOX9 | c.519_521dup p.K173_Y174ins* | Nonsense Mutation (INS) | VAF 86/327 reads (26%) | called by mutect2, pindel, varscan2
- SOX9 | c.1259_1263dup p.P422Tfs*50 | Frame Shift Ins (INS) | VAF 49/192 reads (26%) | called by mutect2, pindel, varscan2
- STAC2 | c.496-2A>G p.X166_splice | Splice Site (SNP) | VAF 16/349 reads (5%) | called by muse, mutect2
- TTC21A | c.2354A>G p.Y785C | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF217 | c.1657_1658insT p.Q553Lfs*10 | Frame Shift Ins (INS) | VAF 111/467 reads (24%) | called by mutect2, pindel, varscan2
- ZNF638 | c.3959C>T p.T1320I | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF737 | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ANKRD30A | c.3726G>C p.T1242= (on ENST00000611781; = p.T1186= on NM_052997.2) | Silent (SNP) | VAF 72/171 reads (42%) | catalogued as COSV64603948; called by muse, mutect2, varscan2
- ATP1A2 | c.1128G>A p.T376= | Silent (SNP) | VAF 49/969 reads (5%) | catalogued as rs374374188; ClinVar: benign / likely benign; called by muse, mutect2
- CREBBP | c.5451G>A p.P1817= | Silent (SNP) | VAF 104/289 reads (36%) | catalogued as rs373848722; called by muse, mutect2, varscan2
- DISC1 | c.147G>A p.S49= | Silent (SNP) | VAF 85/333 reads (26%) | catalogued as rs1002423142; called by muse, mutect2, varscan2
- FAM135B | c.1665C>T p.D555= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as rs757138084, COSV52753154; called by muse, mutect2, varscan2
- FAM189A1 | c.669C>T p.C223= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as rs764555440, COSV54290481; called by muse, mutect2
- FOXP3 | c.1026C>T p.Y342= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as rs374651495; called by muse, mutect2, varscan2
- GLT6D1 | c.417C>T p.T139= | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as rs371852008; called by muse, mutect2, varscan2
- KRT71 | c.1548A>C p.A516= | Silent (SNP) | VAF 52/236 reads (22%) | called by muse, mutect2
- MROH1 | c.2643C>T p.P881= | Silent (SNP) | VAF 40/796 reads (5%) | called by muse, mutect2
- PRR36 | c.3813G>A p.E1271= | Silent (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- SLC5A9 | c.2005T>C p.L669= | Silent (SNP) | VAF 104/355 reads (29%) | called by muse, mutect2, varscan2
- TGIF2LX | c.213G>A p.K71= | Silent (SNP) | VAF 137/444 reads (31%) | called by muse, mutect2, varscan2
- UNC5CL | c.1428C>T p.T476= | Silent (SNP) | VAF 82/287 reads (29%) | catalogued as COSV55110760; called by muse, mutect2, varscan2
- VN1R2 | c.84C>A p.V28= | Silent (SNP) | VAF 31/115 reads (27%) | called by muse, mutect2, varscan2
- DAW1 | c.973+5180G>A | Intron (SNP) | VAF 79/258 reads (31%) | called by muse, mutect2, varscan2
- LINC01583 | n.220G>A | RNA (SNP) | VAF 122/355 reads (34%) | catalogued as rs1306812220; called by muse, mutect2, varscan2
- SSUH2 | c.-89G>A | 5'UTR (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- STAB1 | c.4364-9T>C | Intron (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
